Somatic mutation profile of tumor specimen C3N-01383-01 (aliquot CPT0094230010) from CPTAC case C3N-01383, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 80.5 years (29,417 days).
Specimen C3N-01383-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e442448-1f2a-4dbf-8304-d9a3d11059d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01383-31 (Blood Derived Normal), aliquot CPT0094270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b486656b-f1d2-4641-b1af-d3debddad3c5

The open-access MAF lists 61 somatic variants for this specimen: 39 protein-altering or splice-affecting, 15 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 15, Intron 5, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 2, Splice Site 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 24/296 reads (8%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 32/336 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCB6 | c.2369A>G p.N790S | Missense Mutation (SNP) | VAF 23/325 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs199955293; called by muse, mutect2
- ADAMTS5 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs752801493, COSV53183225; called by muse, mutect2
- BAHCC1 | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs549555237, COSV57023720; called by muse, mutect2, varscan2
- CLASP2 | c.193C>G p.R65G | Missense Mutation (SNP) | VAF 32/307 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV56280376; called by muse, mutect2, varscan2
- COL22A1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.545); catalogued as rs758355984; called by muse, mutect2, varscan2
- COL6A3 | c.9070G>A p.V3024I | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs769756403, COSV55100929; called by muse, mutect2, varscan2
- FAM47A | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.417); catalogued as COSV60497337; called by muse, mutect2, varscan2
- IPO8 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs778254539, COSV56240309; called by muse, mutect2
- MED12L | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1157763534, COSV56404780; called by muse, mutect2, varscan2
- MYPN | c.3206G>A p.R1069H | Missense Mutation (SNP) | VAF 31/459 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs763362861, COSV100590633; ClinVar: uncertain significance; called by muse, mutect2
- NEU4 | c.367C>T p.R123C (on ENST00000391969 / NM_001167602.3; = p.R135C on NM_080741.4) | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs370244576; called by muse, mutect2
- OR14C36 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as rs145207343, COSV58602779; called by muse, mutect2
- OR5D14 | c.733T>A p.S245T | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565114056; called by muse, mutect2, varscan2
- PCED1A | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753469763; called by muse, mutect2
- RIMS2 | c.3548-1G>T p.X1183_splice | Splice Site (SNP) | VAF 24/142 reads (17%) | catalogued as COSV51672175, COSV99165552; called by muse, mutect2, varscan2
- SKIDA1 | c.933_947del p.A314_A318del | In Frame Del (DEL) | VAF 18/98 reads (18%) | catalogued as rs747400271; called by mutect2, varscan2
- SLC39A12 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs187451149; called by muse, mutect2, varscan2
- SLC40A1 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.284); catalogued as rs750595460; called by muse, mutect2
- SMAD4 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 41/259 reads (16%) | catalogued as COSV61691371; called by muse, mutect2, varscan2
- TMPRSS11B | c.301A>T p.K101* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as rs559293322; called by muse, mutect2, varscan2
- TPR | c.637A>G p.R213G | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1174825005; called by muse, mutect2
- UNC79 | c.2317C>T p.R773C (on ENST00000393151 / NM_001346218.2; = p.R596C on NM_020818.5) | Missense Mutation (SNP) | VAF 45/456 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs781756182, COSV56376369; called by muse, mutect2
- AHR | c.1075_1077del p.R359del | In Frame Del (DEL) | VAF 20/235 reads (9%) | called by mutect2, pindel
- COPG2 | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- COX6C | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPD | c.1137+2T>C p.X379_splice | Splice Site (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
- GCLC | c.578G>A p.R193K (on ENST00000643939; = p.R191K on NM_001498.4) | Missense Mutation (SNP) | VAF 36/381 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.051); called by muse, mutect2
- HAUS8 | c.1052A>G p.D351G | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- IFNB1 | c.211T>G p.F71V | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.148); called by muse, mutect2
- KANSL1 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 24/274 reads (9%) | called by muse, mutect2
- MCM8 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC2 | c.2528C>T p.T843I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2
- MYT1L | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PRORP | c.978del p.W326Cfs*30 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- RLF | c.1564del p.Q522Nfs*7 | Frame Shift Del (DEL) | VAF 28/268 reads (10%) | called by mutect2, pindel
- TIPIN | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- UBE2B | c.11del p.P4Rfs*52 | Frame Shift Del (DEL) | VAF 29/269 reads (11%) | called by mutect2, pindel
- ARHGAP23 | c.2433C>T p.G811= | Silent (SNP) | VAF 13/230 reads (6%) | catalogued as rs1199537892; called by muse, mutect2
- BNC1 | c.2904G>A p.S968= | Silent (SNP) | VAF 29/250 reads (12%) | catalogued as rs1021377126, COSV61757413; called by muse, mutect2, varscan2
- CTNNA2 | c.2001C>T p.S667= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as rs368214934; called by muse, mutect2
- DCAF4L2 | c.636C>T p.N212= | Silent (SNP) | VAF 68/358 reads (19%) | catalogued as rs866117569; called by muse, mutect2, varscan2
- ERCC8 | c.129C>T p.G43= | Silent (SNP) | VAF 15/216 reads (7%) | catalogued as rs145518936; called by muse, mutect2
- FLG2 | c.93T>C p.G31= | Silent (SNP) | VAF 18/241 reads (7%) | called by muse, mutect2
- HMCN1 | c.4317T>A p.T1439= | Silent (SNP) | VAF 22/256 reads (9%) | called by muse, mutect2
- NRDE2 | c.906C>T p.S302= | Silent (SNP) | VAF 26/189 reads (14%) | catalogued as rs375950270; called by muse, mutect2, varscan2
- RYR1 | c.12654C>T p.F4218= | Silent (SNP) | VAF 18/296 reads (6%) | catalogued as rs1294294978, COSV62094637; called by muse, mutect2
- SCEL | c.498G>A p.P166= | Silent (SNP) | VAF 21/195 reads (11%) | catalogued as rs528874271; called by muse, mutect2, varscan2
- SLC29A2 | c.577C>T p.L193= | Silent (SNP) | VAF 31/350 reads (9%) | called by muse, mutect2
- SLCO5A1 | c.2190C>T p.N730= | Silent (SNP) | VAF 28/403 reads (7%) | catalogued as COSV52668177; called by muse, mutect2
- SMC4 | c.2775A>G p.V925= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as rs1480861195; called by muse, mutect2
- SUMF2 | c.462C>T p.G154= (on ENST00000652303; = p.G135= on NM_015411.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- VWA5B1 | c.2652C>T p.S884= | Silent (SNP) | VAF 28/274 reads (10%) | catalogued as rs766432055; called by muse, mutect2, varscan2
- AL645933.1 | chr6:31463961 C>G | 5'Flank (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- CA13 | c.37+522T>A | Intron (SNP) | VAF 28/274 reads (10%) | called by muse, mutect2, varscan2
- DNAH14 | c.3537+2471_3537+2476delinsTTTTTT | Intron (ONP) | VAF 4/46 reads (9%) | called by pindel, varscan2*
- IL1RAP | c.538-4962A>T | Intron (SNP) | VAF 14/144 reads (10%) | called by muse, varscan2
- LYRM4 | c.208-3806G>A | Intron (SNP) | VAF 10/81 reads (12%) | catalogued as rs1316186537; called by muse, mutect2, varscan2
- TFAP2C | c.-4C>T | 5'UTR (SNP) | VAF 4/27 reads (15%) | catalogued as rs1423247789, COSV52373804; called by muse, varscan2
- TFR2 | c.614+18C>T | Intron (SNP) | VAF 12/143 reads (8%) | catalogued as rs1398792897; called by muse, mutect2
